Gene-level copy-number profile of tumor specimen TCGA-2G-AAEQ-01A from TCGA case TCGA-2G-AAEQ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 33.8 years (12,337 days).
Specimen TCGA-2G-AAEQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ee529f78-87cd-4ff2-8605-e513a8146ecb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAEQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/f56fcc12-939f-4e21-a426-bdc1cc01d7ae

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 34; copy number 2: 13,634; copy number 3: 30,298; copy number 4: 12,109; copy number 5: 1,675; copy number 6: 327; copy number 8: 16; copy number 9: 710; copy number 10: 64; copy number 15: 1; copy number 76: 43.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,921,328–116,965,227, 3 genes (within-gene range 0–3): AC069504.1, LINC00901, RNU5E-8P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 834 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,562,813–2,838,823, 3 genes, copy number 8: AC245123.1, AC246817.2, AC246817.1.
- chr12:66,767–34,249,958, 831 genes, copy number 8–76 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
